Gene-level copy-number profile of tumor specimen ALCH-B3FU-TTP1-A from ALCHEMIST case ALCH-B3FU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.2 years (25,658 days).
Specimen ALCH-B3FU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 61dbeed2-01a3-4646-b988-38a5cc7abba4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3FU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/c253311a-c2d3-4880-8c3c-1c088882480a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 3,405; copy number 2: 55,371; copy number 3: 45; copy number 4: 10; copy number 5: 3; copy number 6: 8; copy number 8: 1; copy number 12: 6.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:228,149,930–228,159,826, 1 gene: GJC2.
- chr4:1,712,891–1,745,171, 2 genes (within-gene range 0–2): TACC3, TMEM129.
- chr4:3,463,306–3,501,473, 1 gene: DOK7.
- chr7:983,181–989,640, 1 gene: CYP2W1.
- chr7:1,029,025–1,043,891, 1 gene (within-gene range 0–2): AC073957.1.
- chr7:1,530,702–1,543,043, 1 gene (within-gene range 0–2): MAFK.
- chr7:44,217,150–44,334,577, 1 gene: CAMK2B.
- chr7:102,264,706–102,321,711, 3 genes (within-gene range 0–2): AC005088.1, SH2B2, MIR4285.
- chr7:128,790,757–128,862,626, 3 genes (within-gene range 0–2): CCDC136, FLNC, FLNC-AS1.
- chr10:49,364,181–49,396,016, 1 gene: DRGX.
- chr10:133,257,144–133,276,868, 2 genes: AL592071.1, ADAM8.
- chr11:63,985,853–64,166,113, 6 genes (within-gene range 0–2): OTUB1, MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1.
- chr11:116,820,645–116,837,622, 4 genes (within-gene range 0–2): AP006216.3, APOA4, APOC3, APOA1.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr16:2,209,253–2,238,711, 6 genes (within-gene range 0–2): BRICD5, PGP, AC009065.7, E4F1, AC009065.1, DNASE1L2.
- chr16:2,712,419–2,720,551, 1 gene: PRSS27.
- chr17:3,510,502–3,636,249, 5 genes (within-gene range 0–2): TRPV3, TRPV1, AC027796.5, AC027796.3, AC027796.1.
- chr17:47,694,081–47,712,050, 1 gene: TBKBP1.
- chr22:29,705,256–29,767,011, 5 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA.
- chr22:38,424,288–38,455,199, 3 genes: Z97056.1, KCNJ4, Z97056.3.
- chr22:41,551,710–41,577,741, 2 genes (within-gene range 0–2): AL023553.1, CSDC2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,072,767–39,288,315, 1 gene, copy number 12 (within-gene range 4–19): CNTNAP3.
- chr9:39,173,794–39,508,885, 9 genes, copy number 6–12 (within-gene range 6–19): AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3.
- chr14:105,526,583–105,530,202, 1 gene, copy number 5: TMEM121.
- chr14:105,583,731–105,588,395, 1 gene, copy number 6: IGHA2.
- chr14:105,621,116–105,621,180, 1 gene, copy number 8: MIR8071-1.
- chr16:28,688,558–28,735,727, 3 genes, copy number 12 (within-gene range 2–18): EIF3C, CDC37P1, MIR6862-2.
- chr17:81,228,277–81,239,091, 2 genes, copy number 5: TEPSIN, AC027601.1.

Autosomal genes at a single copy (total copy number 1): 584. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
